TARGET case TARGET-10-PANXDB — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/56642ae0-4bb5-5950-afeb-24cb9a1ad01c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 7 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 8.0 years (2,916 days); Year of diagnosis: 2005; Days to last follow up: 3,737 days (10.2 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (1 entry)
- Days to follow up: 3,737 days (10.2 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,737; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Positive.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 97.9 ×10³/µL.
- Day 8: Bone Marrow blast count 80%.
- Day 15: Bone Marrow blast count 30%.
- Day 29: Bone Marrow blast count 4%; Minimal Residual Disease (Flow Cytometry) 1.8%.

Biospecimens (3 samples)
- Sample TARGET-10-PANXDB-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PANXDB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PANXDB-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 3737
- WBC at Diagnosis: 97.87
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 29: 1.8
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Positive
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 80
- BMA Blasts Day 15: 30
- BMA Blasts Day 29: 4
- Karyotype: 48,XY,t(11;12)(q23;q13),+2mar[5]/48,idem,dup(1)(q23q42)[19]/46,XY[1]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: MLL rearranged
